MMRF case MMRF_1722 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/aace550c-5d98-4182-9711-db26a4b4d4a8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 71.6 years (26,149 days); Days to last known disease status: 1,134 days (3.1 years); Days to last follow up: 1,134 days (3.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 71 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 139 days; Days to treatment end: 139 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 141 days; Days to treatment end: 141 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 408 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3: M Protein 1.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.54 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.33 mg/dL; Immunoglobulin G 4.9 g/L; Immunoglobulin A 18.1 g/L; Immunoglobulin M 0.61 g/L; Lactate Dehydrogenase 1.62 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 118 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.28 mmol/L; Albumin 34 g/L; Total Protein 7.5 g/dL; Glucose 12.3 mmol/L; C-Reactive Protein 0.872 mg/dL.
- Day 64 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.01 mg/dL; Immunoglobulin G 7.38 g/L; Immunoglobulin A 0.79 g/L; Immunoglobulin M 1.27 g/L; Beta 2 Microglobulin 2.61 µg/mL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 1.91 ×10⁹/L; Platelets 182 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 7.15 mmol/L.
- Day 168 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.46 mg/dL; Immunoglobulin G 15.9 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 1.92 g/L; Beta 2 Microglobulin 2.81 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 9 ×10⁹/L; Absolute Neutrophil 5.89 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 92.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.05 mmol/L; Albumin 31 g/L; Total Protein 7.3 g/dL; Glucose 6.33 mmol/L.
- Day 289 (ECOG 1): Hemoglobin 8.31 mmol/L; Leukocytes 10.5 ×10⁹/L; Absolute Neutrophil 6.3 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.1 mmol/L; Albumin 32 g/L; Total Protein 6.3 g/dL; Glucose 6.27 mmol/L.
- Day 436 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.59 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 146 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 6.5 g/dL; Glucose 5.28 mmol/L.
- Day 515 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.96 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.81 mg/dL; Immunoglobulin G 15.7 g/L; Immunoglobulin A 1.83 g/L; Immunoglobulin M 0.62 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.18 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 6.6 mmol/L.
- Day 602 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.64 mg/dL; Immunoglobulin G 13.4 g/L; Immunoglobulin A 2.22 g/L; Immunoglobulin M 0.9 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 107 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 36 g/L; Total Protein 7.4 g/dL; Glucose 8.53 mmol/L.
- Day 686 (ECOG 0): Hemoglobin 7.44 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 92 ×10⁹/L.
- Day 770 (ECOG 0): Hemoglobin 8.68 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Glucose 7.87 mmol/L.
- Day 939 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.25 mg/dL; Hemoglobin 8 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 80 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 10.1 mmol/L.
- Day 1,134 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.62 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 2.36 g/L; Immunoglobulin M 0.56 g/L.

Other clinical attributes
- Day -3: Weight: 97 kg; Height: 174 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Bladder Cancer.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1722_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1722_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
